Somatic mutation profile of tumor specimen TCGA-2G-AAGF-01A (aliquot TCGA-2G-AAGF-01A-31D-A42Y-10) from TCGA case TCGA-2G-AAGF, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 28.3 years (10,348 days).
Specimen TCGA-2G-AAGF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d2d28b3-967c-4d42-b20f-80a0ec03fb94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGF-10A (Blood Derived Normal), aliquot TCGA-2G-AAGF-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/688e4876-6685-4494-acf6-27472dff597b

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NEK1 | c.2907T>G p.D969E | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs752555915; called by muse, mutect2
- NIBAN1 | c.1622A>T p.Y541F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373027349; called by muse, mutect2, varscan2
- TRIP6 | c.425C>A p.S142* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99307762; called by muse, mutect2, varscan2
- IRS2 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIM3 | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, varscan2
- RRAGD | c.711_722del p.I238_L241del | In Frame Del (DEL) | VAF 7/46 reads (15%) | called by mutect2, pindel, varscan2
- C2orf74 | c.129G>A p.R43= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs1249394448; called by muse, mutect2, varscan2
- IRAK1 | c.1962G>C p.S654= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV64110656; called by muse, mutect2, varscan2
- CASK | c.1737+51G>A | Intron (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- MRPL15 | c.553+16G>A | Intron (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
